Somatic mutation profile of cancer-model specimen HCM-CSHL-0077-C25-85A (3D Organoid; aliquot HCM-CSHL-0077-C25-85A-01D-A78L-36), derived from the primary tumor of HCMI case HCM-CSHL-0077-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 66.3 years (24,206 days).
Specimen HCM-CSHL-0077-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9408cc3b-0a3e-4d45-8df9-3fa7f4622d97.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0077-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0077-C25-10A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f057c166-8b31-4654-9d63-613be4133cff

The open-access MAF lists 77 somatic variants for this specimen: 50 protein-altering or splice-affecting, 14 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 14, RNA 6, Nonsense Mutation 4, Intron 4, Frame Shift Ins 3, 5'Flank 2, Frame Shift Del 1, Splice Region 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 149/149 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 181/181 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRB1 | c.2116C>G p.P706A | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.025); catalogued as COSV60096936; called by muse, mutect2
- ATP10A | c.3202C>T p.R1068* | Nonsense Mutation (SNP) | VAF 47/84 reads (56%) | catalogued as rs756615616, COSV63522017; called by muse, mutect2, varscan2
- CD79A | c.535G>A p.G179R | Missense Mutation (SNP) | VAF 102/317 reads (32%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs782714583, COSV55739002; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDC42BPB | c.4590G>A p.S1530= | Splice Region (SNP) | VAF 138/245 reads (56%) | catalogued as rs200886335; called by muse, mutect2, varscan2
- CUTC | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 97/524 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs768955316; called by muse, mutect2, varscan2
- DOK5 | c.208C>T p.R70* | Nonsense Mutation (SNP) | VAF 39/341 reads (11%) | catalogued as rs745756056, COSV52815843, COSV52820481; called by muse, mutect2, varscan2
- ERBB4 | c.2779C>T p.R927* | Nonsense Mutation (SNP) | VAF 70/343 reads (20%) | catalogued as rs537458255, COSV61460348; called by muse, mutect2, varscan2
- FAM71C | c.32C>T p.T11M | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs146401531; called by muse, varscan2
- GLI3 | c.2585G>A p.R862H | Missense Mutation (SNP) | VAF 138/678 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1206529384, COSV67886118, COSV67889519; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HEPACAM | c.100G>T p.V34L | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.998); catalogued as rs1427700277; called by muse, mutect2, varscan2
- HNRNPA1 | c.342A>C p.E114D | Missense Mutation (SNP) | VAF 133/288 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.79); catalogued as COSV99043726; called by muse, mutect2, varscan2
- KCND3 | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56192249; called by muse, mutect2, varscan2
- KNCN | c.97G>A p.V33I | Missense Mutation (SNP) | VAF 100/208 reads (48%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.003); catalogued as rs200362801; called by muse, mutect2, varscan2
- MAS1 | c.103G>A p.V35M | Missense Mutation (SNP) | VAF 54/97 reads (56%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs752123270, COSV53121262; called by muse, mutect2, varscan2
- MUC16 | c.20027C>G p.A6676G | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.096); catalogued as COSV101201076, COSV67464315; called by muse, mutect2, varscan2
- PPTC7 | c.325C>T p.R109W | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs755061887, COSV62826808; called by muse, mutect2, varscan2
- RIMS2 | c.2912G>T p.R971L (on ENST00000666250 / NM_001348490.2; = p.R779L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 104/352 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV51668611, COSV99169380; called by muse, mutect2, varscan2
- RIMS2 | c.4541C>T p.P1514L (on ENST00000666250 / NM_001348490.2; = p.P1085L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/241 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51676658; called by muse, mutect2, varscan2
- SALL1 | c.2043C>A p.D681E | Missense Mutation (SNP) | VAF 45/233 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as COSV99174908; called by muse, mutect2, varscan2
- SEMA4C | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 136/311 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as rs1435645867, COSV59692313; called by muse, mutect2, varscan2
- SMAD4 | c.1094G>A p.G365D | Missense Mutation (SNP) | VAF 85/86 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61684480; called by muse, mutect2, varscan2
- SPATA31E1 | c.1070T>C p.I357T | Missense Mutation (SNP) | VAF 102/214 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.697); catalogued as rs774990542; called by muse, mutect2, varscan2
- TNR | c.2714G>A p.R905Q | Missense Mutation (SNP) | VAF 69/125 reads (55%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.544); catalogued as rs527422558; called by muse, mutect2, varscan2
- ZNF366 | c.166C>T p.R56W | Missense Mutation (SNP) | VAF 115/223 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.732); catalogued as COSV59216354; called by muse, mutect2, varscan2
- AMER1 | c.1400G>A p.S467N | Missense Mutation (SNP) | VAF 112/112 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CEP350 | c.5203A>C p.K1735Q | Missense Mutation (SNP) | VAF 66/334 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CHD9 | c.6376dup p.R2126Kfs*6 | Frame Shift Ins (INS) | VAF 37/147 reads (25%) | called by mutect2, pindel, varscan2
- CHST14 | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 94/363 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNOT3 | c.387+1G>A p.X129_splice | Splice Site (SNP) | VAF 17/52 reads (33%) | called by muse, mutect2, varscan2
- CSMD3 | c.5668A>C p.I1890L (on ENST00000297405 / NM_001363185.1; = p.I1786L on NM_052900.3) | Missense Mutation (SNP) | VAF 65/335 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DKK3 | c.362_365del p.N121Rfs*135 | Frame Shift Del (DEL) | VAF 148/342 reads (43%) | called by mutect2, pindel, varscan2
- DNAH3 | c.9126C>A p.S3042R | Missense Mutation (SNP) | VAF 159/255 reads (62%) | SIFT tolerated (0.21); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- DNAH5 | c.10145dup p.L3382Ffs*6 | Frame Shift Ins (INS) | VAF 179/453 reads (40%) | called by mutect2, pindel, varscan2
- EHBP1L1 | c.2110A>T p.T704S | Missense Mutation (SNP) | VAF 100/426 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- GABRA2 | c.674T>A p.I225N | Missense Mutation (SNP) | VAF 55/166 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- GLI3 | c.45dup p.V16Sfs*2 | Frame Shift Ins (INS) | VAF 84/451 reads (19%) | called by mutect2, pindel, varscan2
- IGKV1-9 | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 174/792 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- MAP1B | c.7145C>T p.S2382F | Missense Mutation (SNP) | VAF 17/538 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MORN1 | c.826A>T p.K276* | Nonsense Mutation (SNP) | VAF 165/315 reads (52%) | called by muse, mutect2, varscan2
- MPPED2 | c.539C>A p.T180N | Missense Mutation (SNP) | VAF 99/202 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR5L2 | c.417G>T p.K139N | Missense Mutation (SNP) | VAF 60/238 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- OSGIN2 | c.1220C>A p.S407Y | Missense Mutation (SNP) | VAF 56/398 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OVCH1 | c.3055A>G p.I1019V | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- PCDH10 | c.1611G>T p.K537N | Missense Mutation (SNP) | VAF 96/332 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDHB12 | c.574C>A p.P192T | Missense Mutation (SNP) | VAF 64/187 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RASL10A | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RPS6KA6 | c.1885A>T p.T629S | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- SOAT1 | c.494G>A p.G165E | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- CERKL | c.990C>T p.V330= (on ENST00000339098 / NM_001030311.2; = p.V304= on NM_201548.5) | Silent (SNP) | VAF 79/388 reads (20%) | catalogued as rs139270710; called by muse, mutect2, varscan2
- CLEC17A | c.1083T>C p.D361= | Silent (SNP) | VAF 51/187 reads (27%) | called by muse, mutect2, varscan2
- GOLGB1 | c.5193C>T p.V1731= | Silent (SNP) | VAF 36/166 reads (22%) | called by muse, mutect2, varscan2
- GRIPAP1 | c.1173C>G p.L391= | Silent (SNP) | VAF 115/115 reads (100%) | called by muse, mutect2, varscan2
- HSPB3 | c.231G>T p.V77= | Silent (SNP) | VAF 164/699 reads (23%) | called by muse, mutect2, varscan2
- KTI12 | c.504C>A p.A168= | Silent (SNP) | VAF 48/206 reads (23%) | called by muse, mutect2, varscan2
- LMOD2 | c.73C>T p.L25= | Silent (SNP) | VAF 200/396 reads (51%) | catalogued as COSV101505416; called by muse, mutect2, varscan2
- NR0B1 | c.486G>A p.A162= | Silent (SNP) | VAF 149/304 reads (49%) | called by muse, mutect2, varscan2
- PUF60 | c.498C>T p.T166= (on ENST00000526683 / NM_001362896.2; = p.T149= on NM_014281.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 34/192 reads (18%) | catalogued as rs1208365639; called by muse, mutect2, varscan2
- RALBP1 | c.1317C>G p.L439= | Silent (SNP) | VAF 53/110 reads (48%) | catalogued as COSV50036294; called by muse, mutect2, varscan2
- RIDA | c.57A>G p.G19= | Silent (SNP) | VAF 116/221 reads (52%) | called by muse, mutect2, varscan2
- SCGB2B2 | c.267C>T p.N89= | Silent (SNP) | VAF 71/112 reads (63%) | catalogued as rs546541304; called by muse, mutect2, varscan2
- SIGLEC16 | c.303G>A p.P101= | Silent (SNP) | VAF 198/338 reads (59%) | catalogued as rs748421105; called by muse, mutect2, varscan2
- SULT1C4 | c.312T>C p.H104= | Silent (SNP) | VAF 69/375 reads (18%) | called by muse, mutect2, varscan2
- ANKRD42 | chr11:83193933 G>A | 5'Flank (SNP) | VAF 48/166 reads (29%) | called by muse, mutect2, varscan2
- CRMP1 | chr4:5892782 G>A | 5'Flank (SNP) | VAF 32/58 reads (55%) | called by muse, mutect2, varscan2
- DLG2 | c.205-65795C>T | Intron (SNP) | VAF 50/216 reads (23%) | called by muse, mutect2, varscan2
- DPPA3P2 | n.572G>A | RNA (SNP) | VAF 200/772 reads (26%) | catalogued as rs748760700; called by muse, mutect2, varscan2
- FIBP | c.411+61_411+63del | Intron (DEL) | VAF 181/399 reads (45%) | called by mutect2, pindel, varscan2
- INSR | c.2231+38A>G | Intron (SNP) | VAF 222/367 reads (60%) | catalogued as rs1325123938; called by muse, mutect2, varscan2
- MYADML | n.601C>T | RNA (SNP) | VAF 58/273 reads (21%) | catalogued as rs781180336; called by muse, mutect2, varscan2
- NPIPP1 | n.500G>A | RNA (SNP) | VAF 249/483 reads (52%) | called by muse, mutect2, varscan2
- OCA2 | c.-13C>T | 5'UTR (SNP) | VAF 113/499 reads (23%) | catalogued as COSV100667511; called by muse, mutect2, varscan2
- OVCH1-AS1 | n.232G>A | RNA (SNP) | VAF 42/73 reads (58%) | called by muse, varscan2
- TLK1 | c.330+1121T>C | Intron (SNP) | VAF 105/196 reads (54%) | catalogued as rs965331812; called by muse, mutect2, varscan2
- TUBB7P | n.1230C>T | RNA (SNP) | VAF 65/274 reads (24%) | catalogued as rs782470537; called by muse, mutect2, varscan2
- ZNF849P | n.1080A>T | RNA (SNP) | VAF 109/381 reads (29%) | called by muse, varscan2
